Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17B, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17B-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3

12/4/10
lw

Surgical Pathology

Site Code: Endometrium: C54.1

DIAGNOSIS:

A. Uterus, bilateral ovaries and fallopian tubes, hysterectomy and bilateral salpingo-oophorectomy: FIGO grade II (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (4.0 x 2.7 x 2.7 cm) located in the fundus. The tumor invades superficially, 0.2 cm into the myometrium (total myometrial thickness, 2.5 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are unremarkable and uninvolved.

B-E. Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (11 external iliac, 2 internal iliac, 2 common iliac, and 1 obturator) are negative for tumor.

F-I: Lymph nodes, right pelvic, excision: Multiple right pelvic lymph nodes (11 external iliac, 1 internal iliac, 7 common iliac, 6 obturator) are negative for tumor.

J. Lymph node, additional right pelvic, excision: One additional right pelvic lymph nodes is negative for tumor.

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s).

GROSS DESCRIPTION:

[page 2 of 4]
A. Received fresh labeled "uterus, left and right tubes and ovaries" is a 16.0 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The uterine serosa is smooth.
There is a 4.0 x 2.7 x 2.7 cm mass in the fundus of the endometrial cavity with 2.5 cm myometrial thickness. There is a 2.7 x 1.3 x 1.1 cm right ovary with a smooth outer surface and a solid cut surface with a 9.0 x 0.5 cm right fallopian tube. There is a 2.6 x 1.5 x 0.9 cm left ovary with a smooth outer surface and a solid cut surface with a 7.5 x 0.5 cm left fallopian tube.
Representative sections submitted.

B. Received fresh labeled "left obturator" is a 3.6 x 3.2 x 1.4 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

C. Received fresh labeled "left common iliac" is a 3.4 x 1.8 x 1.1 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

D. Received fresh labeled "left pelvic internal iliac" is a 1.4 x 1.0 x 0.8 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

E. Received fresh labeled "left external iliac" is a 6.0 x 3.2 x 1.9 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

F. Received fresh labeled "right obturator" is a 4.2 x 4.0 x 1.8 cm

[page 3 of 4]
aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

G. Received fresh labeled "right common iliac" is a 3.7 x 2.6 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

H. Received fresh labeled "right internal iliac" is a 1.1 x 1.0 x 0.8 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

I. Received fresh labeled "right external iliac" is a 6.1 x 4.2 x 1.4 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

J. Received fresh labeled "additional right pelvic common lymph nodes" is a 0.6 x 0.5 x 0.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

BLOCK SUMMARY:

Part A: Uterus, left & right tubes and ovaries

- 1 Endometrial mass
- 2 6:00 cervix
- 3 Endometrial mass 2
- 4 Endometrial mass 3
- 5 Endometrium
- 6 Right ovary & tube
- 7 Left ovary & tube

Part B: Left Pelvic Lymph Nodes obturator

- 1 Lt obturator lns 1 (B1)
- 2 Lt obturator lns 3? (B2)

Part C: Left Pelvic Lymph Nodes common

- 1 Lt common lns 1 (C1)
- 2 Lt common lns 2? (C2)

Part D: Left Pelvic Lymph Nodes internal

[page 4 of 4]
1 Lt internal lns 2? (D1)

Part E: Left Pelvic Lymph Nodes external

- 1 Lt external lns 1 (E1)
- 2 Lt external lns 1 (E2)
- 3 Lt external lns 2 (E3)
- 4 Lt external lns 2 (E4)
- 5 Lt external lns 1 (E5)
- 6 Lt external lns 2 (E6)
- 7 Lt external lns 3 (E7)

Part F: Right Pelvic Lymph Nodes obturator

- 1 Rt obturator lns 1 (F1)
- 2 Rt obturator lns 1 (F2)
- 3 Rt obturator lns 1 (F3)

Part G: Right Pelvic Lymph Nodes common

- 1 Rt common lns 1 (G1)
- 2 Rt common lns 2 (G2)
- 3 Rt common lns 4 (G3)

Part H: Right Pelvic Lymph Nodes internal

- 1 Right internal lns 1 (H1)

Part I: Right Pelvic Lymph Nodes external

- 1 Right external lns 2 (I6)
- 2 Right external lns 2 (I1)
- 3 Rt external lns 1 of 2 (I2)
- 4 Rt external lns 2 of 2 (I3)
- 5 Rt external lns 1 (I4)
- 6 Rt external lns 3 (I5)

Part J: Additional right pelvic nodes common

- 1 Additional right common lns

Source: NCI Genomic Data Commons file 70d783c5-d281-4f2f-a98d-d358bdabe480 (TCGA-D1-A17B.FBE330EA-52BC-4B16-A046-3858318348F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).